Somatic mutation profile of tumor specimen TARGET-10-PARTIK-09A (aliquot TARGET-10-PARTIK-09A-01D) from TARGET case TARGET-10-PARTIK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,402 days).
Specimen TARGET-10-PARTIK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c60ebd30-bf3d-4bf2-b27e-abaab6c151b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARTIK-10A (Blood Derived Normal), aliquot TARGET-10-PARTIK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3021338f-9c4d-4f98-8827-ea7b61983bdf

The open-access MAF lists 19 somatic variants for this specimen: 10 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 6, 5'Flank 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 29/79 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PLEC | c.9139G>A p.V3047M (on ENST00000322810 / NM_201380.4; = p.V2937M on NM_000445.5) | Missense Mutation (SNP) | VAF 84/184 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as rs375607727; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SBK2 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.218); catalogued as rs779600909, COSV60015719; called by muse, mutect2, varscan2
- THBS1 | c.2880C>A p.F960L | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV99527785; called by muse, mutect2
- TRGV3 | c.352A>G p.R118G | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs767821628; called by muse, varscan2
- CARMIL2 | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FLRT2 | c.902A>G p.N301S | Missense Mutation (SNP) | VAF 82/195 reads (42%) | SIFT tolerated (0.93); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAPRE2 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- NOL9 | c.2070A>C p.K690N | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRGV3 | c.353G>C p.R118T | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, varscan2
- ARHGEF4 | c.1194C>T p.Y398= | Silent (SNP) | VAF 79/190 reads (42%) | catalogued as rs776424847, COSV58125129; called by muse, mutect2, varscan2
- DTX4 | c.270C>T p.G90= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as rs978082454, COSV57090989; called by muse, mutect2, varscan2
- KRTAP19-4 | c.132C>T p.N44= | Silent (SNP) | VAF 63/159 reads (40%) | catalogued as rs766112768, COSV61858651; called by muse, mutect2, varscan2
- SFTPC | c.561C>T p.T187= | Silent (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2
- SLC5A5 | c.1467C>T p.N489= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs765282766; called by muse, mutect2, varscan2
- TRGV3 | c.354G>A p.R118= | Silent (SNP) | VAF 46/113 reads (41%) | called by muse, varscan2
- SNORD115-21 | chr15:25206407 T>G | 5'Flank (SNP) | VAF 33/80 reads (41%) | called by muse, mutect2, varscan2
- TMEM59L | c.664+67C>A | Intron (SNP) | VAF 18/202 reads (9%) | called by muse, mutect2
- VWFP1 | n.2585C>T | RNA (SNP) | VAF 24/38 reads (63%) | catalogued as rs1309781107; called by muse, mutect2, varscan2
